Somatic mutation profile of tumor specimen C3L-01107-01 (aliquot CPT0128200006) from CPTAC case C3L-01107, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 43.9 years (16,020 days).
Specimen C3L-01107-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa528a6b-d856-43de-b0ca-7752f67c17c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01107-31 (Blood Derived Normal), aliquot CPT0128600002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf0463dd-7ab4-4e4a-883f-0494a4e6b392

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Intron 4, Splice Site 3, Frame Shift Del 2, 5'UTR 1, Translation Start Site 1, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.463+2T>A p.X155_splice | Splice Site (SNP) | VAF 35/255 reads (14%) | hotspot (GDC flag); catalogued as CS961707, COSV56543181, COSV56545468, COSV56553134; called by muse, mutect2, varscan2
- CEP162 | c.3500C>T p.S1167F | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV57618780; called by muse, mutect2
- DPH1 | c.134C>G p.A45G | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99559522; called by muse, mutect2, varscan2
- IL18RAP | c.1367A>T p.D456V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358423594; called by muse, mutect2, varscan2
- NXNL1 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs377352923; called by muse, mutect2
- PLPP1 | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as rs199937515, COSV53303803; called by muse, mutect2, varscan2
- TMEM114 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs775857769; called by muse, mutect2, varscan2
- TRIM60 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 28/299 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.036); catalogued as rs762704763; called by muse, mutect2
- USP5 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.269); catalogued as COSV57531053; called by muse, mutect2, varscan2
- WNT6 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.3); catalogued as COSV52111322; called by muse, mutect2, varscan2
- AFDN | c.4121A>G p.H1374R | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ATP9A | c.2899C>T p.L967F | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CHD9 | c.2992G>T p.E998* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2, varscan2
- CUL9 | c.4339+2del p.X1447_splice | Splice Site (DEL) | VAF 16/133 reads (12%) | called by mutect2, pindel
- CYP2A7 | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DOCK4 | c.5269C>G p.P1757A | Missense Mutation (SNP) | VAF 48/447 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FNDC1 | c.3053del p.G1018Dfs*18 | Frame Shift Del (DEL) | VAF 15/143 reads (10%) | called by mutect2, pindel, varscan2
- GMDS | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPC4 | c.1355T>C p.V452A | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HTR2A | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC4 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2
- LSP1 | c.949A>T p.R317W | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYT1L | c.1-1G>T p.X1_splice | Splice Site (SNP) | VAF 35/324 reads (11%) | called by muse, mutect2, varscan2
- PBRM1 | c.2294del p.G765Efs*10 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- PLCB1 | c.2101A>G p.M701V | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.083); called by muse, mutect2
- PLEKHA7 | c.2147A>C p.K716T | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- SLC12A6 | c.2786T>G p.L929R (on ENST00000354181 / NM_001365088.1; = p.L878R on NM_005135.2) | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC2A13 | c.581_582insAT p.Y195Cfs*11 | Frame Shift Ins (INS) | VAF 15/104 reads (14%) | called by mutect2, pindel, varscan2
- SPATA5L1 | c.635T>A p.L212Q | Missense Mutation (SNP) | VAF 49/365 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- USP37 | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- VXN | c.-1_1delinsT | Translation Start Site (DEL) | VAF 24/164 reads (15%) | called by pindel, varscan2*
- DMXL2 | c.5784T>A p.S1928= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99199268; called by muse, mutect2
- MGA | c.237C>T p.L79= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs373466530; called by muse, mutect2, varscan2
- NLRP1 | c.2443C>T p.L815= | Silent (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2, varscan2
- PIEZO2 | c.954T>C p.C318= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- RBM39 | c.999G>C p.S333= | Silent (SNP) | VAF 25/250 reads (10%) | catalogued as COSV53616708, COSV53617001; called by muse, mutect2, varscan2
- SLC16A8 | c.367C>T p.L123= | Silent (SNP) | VAF 31/216 reads (14%) | called by muse, mutect2, varscan2
- SLC37A3 | c.1158T>G p.L386= | Silent (SNP) | VAF 24/278 reads (9%) | called by muse, mutect2
- ARL13B | c.-4C>T | 5'UTR (SNP) | VAF 42/295 reads (14%) | catalogued as rs768473442; called by muse, mutect2, varscan2
- CDKL1 | c.742-1590C>T | Intron (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- COL24A1 | c.4782+925T>C | Intron (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2
- GRK5 | c.*196G>T | 3'UTR (SNP) | VAF 30/240 reads (13%) | called by muse, mutect2, varscan2
- L1CAM | c.91+10G>C | Intron (SNP) | VAF 43/221 reads (19%) | called by muse, mutect2, varscan2
- SYNE2 | c.17871+206A>C | Intron (SNP) | VAF 44/238 reads (18%) | called by muse, mutect2, varscan2
